Somatic mutation profile of tumor specimen MP2PRT-PAUJGU-TMP1-A (aliquot MP2PRT-PAUJGU-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUJGU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.5 years (544 days).
Specimen MP2PRT-PAUJGU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d4878be-1d1d-4e7a-8b1a-09541bf7c079.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJGU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJGU-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f0f2d9a-065a-4a18-854c-46a26bd9a36c

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 4, Nonsense Mutation 2, In Frame Ins 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APLP2 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 138/292 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs749264722; called by muse, mutect2, varscan2
- DCUN1D3 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 14/458 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV60955421; called by muse, mutect2
- EML1 | c.1879G>T p.E627* | Nonsense Mutation (SNP) | VAF 86/321 reads (27%) | catalogued as COSV51754202, COSV51754845; called by muse, varscan2
- PDE6C | c.1853C>T p.T618M | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); catalogued as rs754752450, COSV65114803; called by muse, mutect2, varscan2
- BAZ1A | c.3846C>G p.F1282L | Missense Mutation (SNP) | VAF 13/450 reads (3%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.086); called by muse, mutect2
- IQUB | c.1594A>T p.K532* | Nonsense Mutation (SNP) | VAF 58/133 reads (44%) | called by muse, mutect2, varscan2
- MAN2A2 | c.2976_2978dup p.R993dup | In Frame Ins (INS) | VAF 130/396 reads (33%) | called by mutect2, pindel, varscan2
- SLCO1A2 | c.208_210dup p.L72dup | In Frame Ins (INS) | VAF 16/162 reads (10%) | called by mutect2, pindel
- DPYSL3 | c.1059G>A p.E353= | Silent (SNP) | VAF 115/376 reads (31%) | catalogued as rs778946047; called by muse, mutect2, varscan2
- EDNRA | c.1272C>T p.D424= | Silent (SNP) | VAF 23/442 reads (5%) | called by muse, mutect2
- HK3 | c.2463C>T p.D821= | Silent (SNP) | VAF 34/623 reads (5%) | catalogued as rs200491262, COSV99457540; called by muse, mutect2
- RBM41 | c.339T>C p.T113= | Silent (SNP) | VAF 171/440 reads (39%) | called by muse, mutect2, varscan2
- SHISAL2A | c.390G>C p.V130= | Silent (SNP) | VAF 34/405 reads (8%) | catalogued as COSV68979699, COSV68980133; called by muse, mutect2
- SLC4A4 | c.2814C>T p.D938= (on ENST00000264485 / NM_001098484.3; = p.D894= on NM_003759.4) | Silent (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- IDS | c.418+109G>T | Intron (SNP) | VAF 127/347 reads (37%) | catalogued as COSV61712493; called by muse, mutect2, varscan2
